Somatic mutation profile of tumor specimen 0DDHVM from CCDI case PBBNWV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.4 years (1,616 days).
Specimen 0DDHVM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74ccf652-b588-4d0c-b417-a2ef8e2e038a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDHVN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d1de0a-8f67-415a-9492-593b0be60011

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH18A1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); catalogued as rs1185868272; called by muse, mutect2, varscan2
- ALDOC | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 26/230 reads (11%) | catalogued as rs149843711; called by muse, mutect2, varscan2
- FDXR | c.830C>T p.T277M (on ENST00000293195 / NM_024417.5; = p.T283M on NM_004110.6) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as rs767942793; called by muse, mutect2, varscan2
- KLF4 | c.436T>A p.S146T | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV65929219; called by muse, mutect2, varscan2
- HSPH1 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 223/555 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX21 | c.1067C>A p.T356N | Missense Mutation (SNP) | VAF 124/280 reads (44%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.601); called by mutect2, varscan2
- C1QTNF1 | c.90C>T p.V30= | Silent (SNP) | VAF 80/310 reads (26%) | called by muse, mutect2
- TTC22 | c.624-9C>T | Intron (SNP) | VAF 62/250 reads (25%) | catalogued as rs778142210; called by muse, mutect2, varscan2
